Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A5GO, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A5GO-06A (Metastatic).

[page 1 of 2]
***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) RIGHT UPPER ARM, SKIN ELLIPSE:

MELANOMA IN DEEP DERMIS AND SUBCUTANEOUS ADIPOSE TISSUE.

TUMOR SIZE: 13.0 X 13.0 MM, (AS PER GROSS DESCRIPTION).

TUMOR BORDER: PUSHING.

Margins have been evaluated and are free of melanoma.

(B) ADDITIONAL MEDIAL MARGIN, SKIN ELLIPSE:

Skin and subcutis, negative for melanoma.

(C) RIGHT FOREARM, SKIN PUNCH:

Solar elastosis.

Melanoma is not identified in multiple sections examined.

Additional sections throughout the paraffin block are being requested. Results will be reported in an addendum.

ICD-O-3

Melanoma, malignant NOS

8720/3

Site: Skin of Arm

044.6

yo 4/4/13

Per TSS - after re-review of case, PI classifies as distant mets

GROSS DESCRIPTION

(A) RIGHT UPPER ARM, WIDE LOCAL RECURRENT MELANOMA, SHORT STITCH PROXIMAL, LONG STITCH LATERAL - An ellipse of tan skin and underlying tissue measuring 7.0 x 3.0 x 1.5 cm. The skin surface is focally bulging. Surgical margins are inked. Sectioning through the bulging skin reveals a well demarcated black-brown nodule situated right beneath the skin, 0.5 cm from the medial peripheral soft tissue surgical margin and 0.9 cm from the deep surgical margin. The nodule is 1.5 cm away from the lateral peripheral surgical margin. The nodule itself measures 1.3 x 1.3 x 1.0 cm. A portion of the nodule is submitted to melanoma Tumor Bank. The rest of the nodule is submitted in sequential order from proximal toward distal aspect.

INK CODE: Medial - peripheral surgical margin inked blue; lateral - yellow.

SECTION CODE: A1, proximal tip; A2, distal tip; A3-A6, rest of the nodule sequentially submitted. Each section contains medial and deep surgical margins; A7, shaved lateral surgical margin.

(B) ADDITIONAL MEDIAL MARGIN, STITCH AT THE MARGIN - An ellipse of tan, grossly unremarkable skin and underlying tissue measuring 3.5 x 0.6 x 0.5 cm. True surgical margin is inked blue. True surgical margin is shaved and entirely submitted ink side up in cassette B.

(C) RIGHT FOREARM LESION, PUNCH BIOPSY - A shallow skin punch biopsy measuring 0.8 x 0.7 x 0.2 cm. Surgical margin is inked blue. The skin surface is focally hyperpigmented. Cut surface shows a small area of hemorrhage situated right beneath the skin surface measuring 0.1 x 0.1 x 0.1 cm. Entirely submitted in cassette C

CLINICAL HISTORY

Melanoma, right upper arm.

SNOMED CODES

T-02610, T-02630, M-87602

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 2 of 2]
ADDENDUM

This modified report is being issued to report additional step sections on specimen C.

Addendum completed by _____

DIAGNOSIS

- (C) RIGHT FOREARM, SKIN PUNCH:
Hemangioma, present at tissue edge.
Melanoma is not identified.

COMMENT

(C) The entire block of the specimen C has been examined. A deep dermal hemangioma is present. Melanocytic lesion is not identified.

SNOMED CODES

M-91200

Entire report and diagnosis completed by:

-----END OF REPORT-----

HIVAA Discrepancy		/

Source: NCI Genomic Data Commons file 130d2cba-e020-4339-9149-97bdb445a78c (TCGA-D3-A5GO.FFFA2FD5-C008-4583-99C9-EE71B0F21F07.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).